TCGA case TCGA-UF-A7JO — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/55deab98-29c3-45a1-bc13-bce3f13ad481

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 79 years; Vital status: Dead; Days to death: 631 days (1.7 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 79.3 years (28,951 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 27; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 214 days; Days to treatment end: 265 days; Treatment dose: 6,120 cGy; Treatment outcome: Complete Response; Number of fractions: 34; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 214 days; Days to treatment end: 250 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Floor of mouth, NOS. Age at diagnosis: 80.7 years (29,476 days); Days to diagnosis: 525 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 614 days (1.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 525 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Floor of mouth, NOS; Days to recurrence: 525 days (1.4 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 631 days (1.7 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UF-A7JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 110 mg.
  Slide TCGA-UF-A7JO-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UF-A7JO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UF-A7JO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 1; Alcohol history documented: No; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 631 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 631 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 525 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UF-A7JO-01A-11D-A34I-01): tumor purity 0.43, ploidy 1.89, whole-genome doublings 0.
